Somatic mutation profile of tumor specimen C3N-02591-01 (aliquot CPT0162710028) from CPTAC case C3N-02591, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.1 years (22,332 days).
Specimen C3N-02591-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee8e4557-d65b-4e9a-81e0-51ec8ecb723d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02591-31 (Blood Derived Normal), aliquot CPT0162750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6906c3d9-46bc-48a1-827a-ff2356f5c36b

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Nonsense Mutation 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 50/572 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.1059C>G p.Y353* | Nonsense Mutation (SNP) | VAF 47/486 reads (10%) | catalogued as rs863224400, COSV100747403, COSV100748382; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 37/387 reads (10%) | catalogued as rs1212996409, COSV52698907, COSV52754015, COSV53086342, COSV53313307; ClinVar: pathogenic; called by muse, mutect2
- APAF1 | c.2134C>T p.H712Y (on ENST00000551964 / NM_181861.2; = p.H701Y on NM_001160.3) | Missense Mutation (SNP) | VAF 51/493 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs754439819; called by muse, mutect2, varscan2
- BEST3 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs756507092; called by muse, mutect2, varscan2
- CSMD1 | c.6491C>T p.P2164L (on ENST00000520002; = p.P2163L on NM_033225.6) | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772713616; called by muse, mutect2
- ENAM | c.3263C>T p.T1088M | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139404568; called by muse, mutect2
- LRRC28 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1299175602, COSV57341582; called by muse, mutect2, varscan2
- PGAM5 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766921845; called by muse, mutect2
- PRODH2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV56559846; called by muse, mutect2
- ROBO2 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 23/467 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs555617157, COSV59902591; called by muse, mutect2
- SIL1 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 232/1237 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.685); catalogued as rs545999438, COSV54537663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVEP1 | c.2735A>G p.Y912C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs758966364; called by muse, mutect2
- TRIML2 | c.1050G>T p.W350C | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1161631383; called by muse, mutect2
- ADAM12 | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADGRL3 | c.572G>T p.C191F (on ENST00000506720 / NM_001322402.2; = p.C123F on NM_015236.6) | Missense Mutation (SNP) | VAF 33/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CCDC80 | c.38T>A p.L13* | Nonsense Mutation (SNP) | VAF 28/263 reads (11%) | called by muse, varscan2
- CPS1 | c.2374A>G p.M792V | Missense Mutation (SNP) | VAF 50/688 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- CYBRD1 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 56/652 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.07); called by muse, mutect2
- GLIS1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); called by muse, mutect2
- GNG4 | c.221T>G p.I74S | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- MCM3AP | c.2491G>C p.V831L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); called by muse, mutect2
- MSH5 | c.521T>G p.F174C | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- OR1C1 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 60/620 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- OR5B3 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PEAR1 | c.1357T>G p.C453G | Missense Mutation (SNP) | VAF 12/365 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHLDA2 | c.332G>C p.R111P | Missense Mutation (SNP) | VAF 57/457 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- RCOR1 | c.1245del p.K415Nfs*6 | Frame Shift Del (DEL) | VAF 35/364 reads (10%) | called by mutect2, pindel, varscan2
- ZBTB49 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- BRD2 | c.1542A>G p.E514= | Silent (SNP) | VAF 26/398 reads (7%) | catalogued as rs201425304; called by muse, mutect2
- KMT2D | c.16296G>C p.R5432= | Silent (SNP) | VAF 31/266 reads (12%) | called by muse, mutect2
- OBSCN | c.13173C>T p.F4391= | Silent (SNP) | VAF 28/600 reads (5%) | catalogued as rs748377121, COSV52777625; called by muse, mutect2
- PADI6 | c.1221C>T p.D407= | Silent (SNP) | VAF 21/331 reads (6%) | catalogued as rs770970009; called by muse, mutect2
- PCDHB11 | c.1449C>T p.N483= | Silent (SNP) | VAF 149/1122 reads (13%) | catalogued as rs1281698776, COSV61309938, COSV61314106; called by muse, mutect2, varscan2
- PTPRS | c.1770C>T p.Y590= | Silent (SNP) | VAF 58/427 reads (14%) | catalogued as rs1013500413, COSV53612308; called by muse, varscan2
- SIRPB1 | c.748C>A p.R250= | Silent (SNP) | VAF 54/633 reads (9%) | called by muse, mutect2
- SLC35D3 | c.387G>T p.S129= | Silent (SNP) | VAF 52/393 reads (13%) | called by muse, mutect2, varscan2
- TRAV10 | c.240C>T p.N80= | Silent (SNP) | VAF 33/371 reads (9%) | catalogued as rs189035449; called by muse, mutect2
- TST | c.228C>T p.P76= | Silent (SNP) | VAF 35/280 reads (13%) | catalogued as rs1326909882; called by muse, mutect2, varscan2
- VPS4B | c.963C>T p.L321= | Silent (SNP) | VAF 40/616 reads (6%) | catalogued as rs781217222; called by muse, mutect2
- WDR62 | c.147G>T p.S49= | Silent (SNP) | VAF 50/412 reads (12%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3513G>A | Intron (SNP) | VAF 36/457 reads (8%) | called by muse, mutect2
